Somatic mutation profile of tumor specimen TCGA-SP-A6QJ-01A (aliquot TCGA-SP-A6QJ-01A-11D-A35I-08) from TCGA case TCGA-SP-A6QJ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 64.1 years (23,406 days).
Specimen TCGA-SP-A6QJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de349e50-d230-47a3-ac63-eb01647e2c08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SP-A6QJ-10A (Blood Derived Normal), aliquot TCGA-SP-A6QJ-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d965c0f1-7ad4-4fe0-a265-afd67daef200

The open-access MAF lists 10 somatic variants for this specimen: 10 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 31/72 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNA1F | c.5579C>T p.A1860V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs2856748, COSV59902937; called by muse, mutect2, varscan2
- CHSY3 | c.1912A>G p.M638V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs767365800; called by muse, mutect2, varscan2
- H1-7 | c.303G>T p.R101S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs1254216518, COSV58602550; called by muse, mutect2, varscan2
- HUWE1 | c.5987G>T p.R1996L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV53364820; called by muse, mutect2, varscan2
- ARNT | c.242_246del p.Q81Lfs*4 | Frame Shift Del (DEL) | VAF 46/118 reads (39%) | called by mutect2, pindel, varscan2
- FLNB | c.2772del p.Y924* | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | called by mutect2, pindel, varscan2
- PDLIM5 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- SKA3 | c.326A>C p.N109T | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- TRAV3 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
